Somatic mutation profile of tumor specimen TCGA-CV-7250-01A (aliquot TCGA-CV-7250-01A-11D-2012-08) from TCGA case TCGA-CV-7250, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 64.3 years (23,489 days).
Specimen TCGA-CV-7250-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6dd2b3f-1981-4dfc-9a1e-157624c127ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7250-10A (Blood Derived Normal), aliquot TCGA-CV-7250-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e986941-fbce-4c64-9d85-3426c2039e2a

The open-access MAF lists 219 somatic variants for this specimen: 162 protein-altering or splice-affecting, 56 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 136, Silent 56, Nonsense Mutation 11, Frame Shift Del 9, Frame Shift Ins 3, Splice Site 2, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLB1 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780724173, CM064028, COSV56566122; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 22/82 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 21/93 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.497T>A p.V166D | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV100416390; called by muse, mutect2, varscan2
- ALPK3 | c.1927G>T p.A643S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.049); catalogued as COSV99360680; called by muse, mutect2, varscan2
- AMY2A | c.1318G>C p.G440R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1415139372; called by mutect2, varscan2
- ARNT | c.555G>T p.R185S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100591077, COSV62231932; called by muse, mutect2, varscan2
- ARPP21 | c.2119A>T p.N707Y | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs749862781, COSV99491669; called by muse, mutect2, varscan2
- ASB16 | c.79G>C p.D27H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99518820; called by muse, mutect2, varscan2
- ATP13A4 | c.2608G>C p.A870P | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100710269; called by muse, mutect2, varscan2
- BAZ1A | c.2804G>A p.R935H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs116485187, COSV100701124; called by muse, mutect2, varscan2
- BRCA1 | c.4934G>T p.R1645M | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs70953661, COSV100523868, COSV99070816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CA10 | c.617C>G p.T206R | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99562490; called by muse, mutect2
- CACNG6 | c.44G>C p.R15P | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as COSV99403302, COSV99403386; called by muse, mutect2
- CCDC117 | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as COSV99968843; called by muse, mutect2, varscan2
- CCDC40 | c.1874G>T p.R625M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100884245; called by muse, mutect2, varscan2
- CCDC50 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV66667794; called by muse, mutect2, varscan2
- CCER1 | c.208C>A p.Q70K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.655); catalogued as rs778264837, COSV100727000, COSV62646150; called by muse, mutect2, varscan2
- CD1D | c.715A>T p.M239L | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as COSV100939581, COSV63810196; called by muse, mutect2
- CD84 | c.839C>G p.T280R (on ENST00000311224 / NM_001184879.2; = p.T263R on NM_003874.4) | Missense Mutation (SNP) | VAF 21/377 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100245960; called by muse, mutect2
- CDK4 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.072); catalogued as rs779161525, COSV99225952; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP250 | c.2704C>T p.Q902* | Nonsense Mutation (SNP) | VAF 10/91 reads (11%) | catalogued as rs1374427601, COSV100698869; called by muse, mutect2, varscan2
- CERK | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs768926363, COSV99348540; called by muse, mutect2, varscan2
- CERS2 | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as rs1204828874, COSV99644372; called by muse, mutect2, varscan2
- CES2 | c.1409G>A p.G470E | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.139); catalogued as COSV100399186; called by muse, mutect2, varscan2
- CFAP70 | c.1514G>A p.G505E | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.84); catalogued as COSV100160451; called by muse, mutect2, varscan2
- CLSPN | c.1211dup p.N404Kfs*2 | Frame Shift Ins (INS) | VAF 16/119 reads (13%) | catalogued as rs1455213253; called by mutect2, pindel, varscan2
- COL11A1 | c.3530G>A p.G1177E | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100616009; called by muse, mutect2, varscan2
- COL3A1 | c.2956A>T p.N986Y | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100482840; called by muse, mutect2, varscan2
- COL6A6 | c.6175G>T p.A2059S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as COSV100650158; called by muse, mutect2, varscan2
- DNAH9 | c.3314T>G p.L1105R | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.091); catalogued as COSV99305298; called by muse, mutect2, varscan2
- DPP6 | c.397G>C p.V133L (on ENST00000377770 / NM_001364500.2; = p.V71L on NM_001936.5) | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as COSV100124640; called by muse, mutect2, varscan2
- DZIP3 | c.872G>T p.C291F | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV64312509; called by muse, mutect2, varscan2
- EGFR | c.685A>T p.S229C | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV51827895; called by muse, mutect2, varscan2
- EIF3M | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV60072800; called by muse, mutect2, varscan2
- EPB41L3 | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.965); catalogued as rs548784436, COSV100548731; called by muse, mutect2, varscan2
- ERBB2 | c.2748G>A p.M916I | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99507544; called by muse, mutect2
- ERICH3 | c.2636A>G p.Q879R | Missense Mutation (SNP) | VAF 76/244 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV100443980; called by muse, mutect2, varscan2
- FAM184A | c.1349A>G p.K450R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100137667; called by muse, mutect2, varscan2
- FAM71B | c.1186G>C p.G396R | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.564); catalogued as COSV100262026; called by muse, mutect2, varscan2
- FAR2 | c.1056G>A p.W352* | Nonsense Mutation (SNP) | VAF 21/277 reads (8%) | catalogued as COSV99478967; called by muse, mutect2
- FAT1 | c.4007C>G p.S1336* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | catalogued as COSV101499276; called by muse, mutect2, varscan2
- FAT3 | c.6733C>T p.P2245S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.161); catalogued as rs1467005475, COSV99964745; called by muse, mutect2, varscan2
- FGFR4 | c.471G>C p.K157N | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99449527; called by muse, mutect2, varscan2
- FUT9 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100133274, COSV100133413; called by muse, mutect2, varscan2
- GHSR | c.478G>A p.V160M | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM077844, COSV99576862; called by muse, mutect2, varscan2
- GLIPR1 | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99875622; called by muse, mutect2
- GPR119 | c.495C>A p.F165L | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as COSV99358602, COSV99358659; called by muse, mutect2, varscan2
- GRB10 | c.1081G>T p.G361W (on ENST00000398812; = p.G315W on NM_001001549.3) | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100240223; called by muse, mutect2, varscan2
- GRK5 | c.371A>C p.D124A | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV100962993; called by muse, varscan2
- GRM3 | c.122T>C p.L41S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100862446; called by muse, mutect2, varscan2
- H2BC8 | c.32C>G p.P11R | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV99773174; called by muse, mutect2
- HEPHL1 | c.1233T>G p.S411R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.57); catalogued as COSV100243817; called by muse, mutect2, varscan2
- HFM1 | c.494G>C p.R165T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.098); catalogued as rs1221376362, COSV99645849; called by mutect2, varscan2
- HIVEP3 | c.6006A>T p.E2002D | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99912261; called by muse, mutect2, varscan2
- HIVEP3 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as COSV99912263; called by muse, mutect2, varscan2
- HSP90AB1 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100807040; called by muse, mutect2, varscan2
- HSPA4L | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99612866; called by muse, mutect2, varscan2
- IKZF2 | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100563429; called by muse, mutect2, varscan2
- IL36A | c.179G>C p.G60A | Missense Mutation (SNP) | VAF 63/293 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99382096; called by muse, mutect2, varscan2
- IL4 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as COSV99184994; called by muse, mutect2, varscan2
- ITPR1 | c.5189A>G p.H1730R (on ENST00000354582; = p.H1723R on NM_001168272.2) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs968484890, COSV100230704; called by muse, mutect2, varscan2
- JPH2 | c.76C>A p.H26N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100652554; called by muse, mutect2, varscan2
- KIR2DL1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs757909487, COSV52406138; called by muse, mutect2, varscan2
- KRTAP19-7 | c.44G>A p.C15Y | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1208189945, COSV100603180; called by muse, mutect2, varscan2
- KRTAP5-10 | c.433T>C p.C145R | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.143); catalogued as COSV100924135; called by muse, mutect2, varscan2
- LMBRD1 | c.824C>G p.S275* (on ENST00000649011; = p.S253* on NM_018368.4) | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV65297939; called by muse, mutect2, varscan2
- LRRC40 | c.1481T>A p.L494Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100918744; called by muse, mutect2, varscan2
- MAGEB18 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV100305421; called by muse, mutect2, varscan2
- MAN2A2 | c.2281A>C p.S761R | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as COSV100847827; called by muse, mutect2, varscan2
- MAPK11 | c.347T>A p.I116N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV100404442; called by muse, mutect2, varscan2
- MAPKBP1 | c.1471G>C p.G491R (on ENST00000456763 / NM_001128608.2; = p.G485R on NM_014994.3) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99529230; called by muse, mutect2, varscan2
- MDN1 | c.12762-2A>G p.X4254_splice | Splice Site (SNP) | VAF 14/51 reads (27%) | catalogued as COSV101021140; called by muse, mutect2, varscan2
- MERTK | c.2636A>G p.E879G | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs1280613658, COSV99774465; called by muse, mutect2, varscan2
- MME | c.484C>G p.P162A | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV100852357; called by muse, mutect2, varscan2
- MYH8 | c.694G>C p.A232P | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101238363; called by muse, mutect2, varscan2
- N4BP3 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as rs776453844, COSV99200646; called by muse, mutect2, varscan2
- NAIP | c.401A>G p.N134S | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99519245; called by muse, mutect2, varscan2
- NEB | c.9543C>G p.D3181E | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.287); catalogued as COSV99420075; called by muse, mutect2
- NECAB3 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs748075553, COSV99864655; called by mutect2, varscan2
- NOL4 | c.1820A>G p.N607S | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.546); catalogued as rs1359987642, COSV99306006; called by muse, mutect2, varscan2
- NOVA1 | c.643A>T p.N215Y | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99947199; called by muse, mutect2, varscan2
- NRP2 | c.954G>T p.W318C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99784066; called by muse, mutect2, varscan2
- NSA2 | c.40T>A p.Y14N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as COSV99713653; called by mutect2, varscan2
- NSD1 | c.4076C>A p.S1359* | Nonsense Mutation (SNP) | VAF 80/115 reads (70%) | catalogued as COSV61772897; called by muse, mutect2, varscan2
- NXPE3 | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 7/107 reads (7%) | catalogued as COSV99839893; called by muse, mutect2
- OR4K5 | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 59/368 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60002738, COSV60005770; called by muse, mutect2, varscan2
- OR6T1 | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100189880, COSV58310134; called by muse, mutect2, varscan2
- OR8G1 | c.778T>A p.L260M | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100422370; called by muse, mutect2, varscan2
- OR8S1 | c.778C>G p.L260V | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.479); catalogued as COSV100043523; called by muse, mutect2, varscan2
- OXGR1 | c.260C>A p.P87H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747928220, COSV100036951; called by muse, mutect2, varscan2
- PCDHA13 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.967); catalogued as COSV99165748; called by muse, mutect2, varscan2
- PCDHA8 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1481721691, COSV100970639; called by muse, varscan2
- PCDHGB1 | c.2147G>T p.S716I | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as COSV99535753; called by muse, mutect2
- PDGFC | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs141820181, COSV56854867; called by muse, mutect2, varscan2
- PDZK1 | c.1271T>C p.I424T | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.597); catalogued as rs781967147, COSV100572417; called by muse, mutect2, varscan2
- PHKB | c.1100T>C p.I367T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV100066556; called by muse, mutect2, varscan2
- PLEKHN1 | c.710G>A p.R237H (on ENST00000379409; = p.R197H on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs370898773; called by mutect2, varscan2
- PLEKHS1 | c.887C>A p.S296Y (on ENST00000369310 / NM_182601.1; = p.S302Y on NM_024889.5) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.165); catalogued as COSV100613070; called by muse, mutect2, varscan2
- PLPP4 | c.346T>A p.C116S | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100956294; called by muse, mutect2, varscan2
- PLPPR4 | c.1744A>C p.M582L | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as COSV100926767; called by muse, mutect2, varscan2
- PRDM2 | c.3042del p.T1015Pfs*26 | Frame Shift Del (DEL) | VAF 36/118 reads (31%) | catalogued as COSV99341119; called by mutect2, pindel, varscan2
- PSG7 | c.581A>T p.Q194L | Missense Mutation (SNP) | VAF 150/423 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV101343224; called by muse, mutect2, varscan2
- PTPN13 | c.5978G>A p.G1993E (on ENST00000411767 / NM_080683.3; = p.G1974E on NM_006264.3) | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100364563; called by muse, mutect2
- PXDN | c.3596A>G p.E1199G | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as COSV99413129; called by muse, mutect2, varscan2
- ROCK2 | c.727G>A p.G243S | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99837249; called by muse, mutect2, varscan2
- RSPO2 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99409379; called by muse, mutect2, varscan2
- RUFY2 | c.1271C>G p.T424S | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV56261017, COSV99769213; called by muse, mutect2, varscan2
- RXRG | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.165); catalogued as COSV100717428, COSV63232922; called by muse, mutect2, varscan2
- SCIN | c.1406T>C p.V469A (on ENST00000297029 / NM_001112706.3; = p.V222A on NM_033128.3) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99764738; called by muse, mutect2, varscan2
- SCPEP1 | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99227789; called by muse, mutect2
- SEC16B | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.288); catalogued as rs770506272, COSV57623810; called by mutect2, varscan2
- SENP6 | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.163); catalogued as COSV100519104; called by muse, mutect2, varscan2
- SERTAD1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.062); catalogued as COSV100781677, COSV100781699; called by muse, mutect2, varscan2
- SI | c.4124C>A p.A1375D | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.158); catalogued as COSV100015071; called by muse, mutect2, varscan2
- SIGLEC9 | c.1282G>T p.E428* | Nonsense Mutation (SNP) | VAF 9/88 reads (10%) | catalogued as COSV99142505; called by muse, mutect2, varscan2
- SKAP1 | c.908G>A p.W303* | Nonsense Mutation (SNP) | VAF 13/93 reads (14%) | catalogued as COSV100411651; called by muse, mutect2, varscan2
- SLC12A6 | c.2893dup p.Y965Lfs*6 (on ENST00000354181 / NM_001365088.1; = p.Y914Lfs*6 on NM_005135.2) | Frame Shift Ins (INS) | VAF 17/57 reads (30%) | catalogued as rs1275422176; called by mutect2, pindel, varscan2
- SLC19A3 | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV51453399; called by muse, mutect2, varscan2
- SLC20A1 | c.1531G>A p.V511I | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV99733998; called by muse, mutect2
- SLC27A6 | c.988C>A p.H330N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52487743, COSV99322560; called by muse, mutect2
- SLC2A2 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58585659; called by muse, mutect2, varscan2
- SLC8A3 | c.238T>C p.Y80H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100776087; called by muse, mutect2, varscan2
- SLITRK6 | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs755293525, COSV68390369; called by muse, mutect2, varscan2
- SMARCA2 | c.1998C>A p.S666R | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV100570714, COSV61812664; called by muse, mutect2, varscan2
- SMARCA4 | c.1508C>A p.A503E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100758420; called by muse, mutect2, varscan2
- SMARCA4 | c.3484G>T p.G1162C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100759311, COSV60788440, COSV60801054; called by muse, mutect2, varscan2
- SNAPC2 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV99684024; called by muse, mutect2, varscan2
- SOX5 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.174); catalogued as COSV100506590; called by muse, mutect2, varscan2
- SULT1A1 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs764663532, COSV100131753; called by mutect2, varscan2
- SULT1B1 | c.262G>T p.G88* | Nonsense Mutation (SNP) | VAF 32/107 reads (30%) | catalogued as COSV100150203; called by muse, mutect2, varscan2
- SV2A | c.2167C>T p.L723F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV100975104; called by muse, mutect2, varscan2
- SYNE1 | c.25241C>T p.T8414M (on ENST00000367255 / NM_182961.4; = p.T8366M on NM_033071.3) | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs759512753, COSV54946518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNGR1 | c.469T>G p.S157A | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99335559; called by muse, mutect2, varscan2
- TARDBP | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV99534127; called by muse, mutect2
- TCEAL2 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100216287; called by muse, mutect2, varscan2
- TEK | c.3103G>T p.G1035* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV101193347; called by muse, mutect2, varscan2
- TEX13A | c.773C>A p.T258N | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV100781144; called by muse, mutect2, varscan2
- TIAM2 | c.1372A>G p.I458V | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.994); catalogued as rs758846679, COSV100018623; called by muse, mutect2, varscan2
- TJP1 | c.4288C>G p.P1430A | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100632599; called by muse, mutect2, varscan2
- TJP1 | c.1252C>T p.L418F | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as COSV100632600; called by muse, mutect2, varscan2
- TMEM132B | c.2405A>G p.D802G | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.935); catalogued as COSV100169272; called by muse, mutect2
- TSHZ1 | c.3131G>A p.R1044Q (on ENST00000580243 / NM_001308210.2; = p.R999Q on NM_005786.6) | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs557571956, COSV100433443; called by muse, mutect2, varscan2
- TSPY1 | c.583C>G p.P195A | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV101369650; called by muse, mutect2, varscan2
- ZEB2 | c.2677C>T p.P893S | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.3); catalogued as COSV57960225, COSV57965527, COSV57967563; called by muse, mutect2
- ZNF385D | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV99874280; called by muse, mutect2, varscan2
- ZNF550 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as COSV100286552; called by muse, mutect2, varscan2
- ZNF568 | c.1427G>A p.C476Y | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100451246; called by muse, mutect2, varscan2
- ZNF585B | c.1153A>T p.S385C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); catalogued as COSV100459399; called by muse, mutect2, varscan2
- ZNF608 | c.3035G>T p.G1012V | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV100101479; called by muse, mutect2, varscan2
- CDHR2 | c.270_271del p.Y91Hfs*26 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | called by pindel, varscan2
- F2RL3 | c.110-22_111del p.X37_splice | Splice Site (DEL) | VAF 12/114 reads (11%) | called by mutect2, pindel
- FBH1 | c.1638del p.K547Rfs*5 (on ENST00000362091 / NM_178150.3; = p.K598Rfs*5 on NM_032807.4) | Frame Shift Del (DEL) | VAF 17/89 reads (19%) | called by mutect2, pindel, varscan2
- KIAA1217 | c.3532_3534del p.K1178del | In Frame Del (DEL) | VAF 24/63 reads (38%) | called by pindel, varscan2
- KIR3DL1 | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- MGAT4B | c.230_233del p.E77Gfs*16 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- NEK4 | c.1852_1853del p.R618Efs*45 | Frame Shift Del (DEL) | VAF 48/192 reads (25%) | called by pindel, varscan2
- NLRP14 | c.1047del p.M350* | Frame Shift Del (DEL) | VAF 23/79 reads (29%) | called by mutect2, pindel, varscan2
- PGS1 | c.836del p.D279Afs*32 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | called by mutect2, pindel
- THSD7B | c.4257dup p.Q1420Tfs*26 (on ENST00000272643; = p.Q1418Tfs*26 on NM_001316349.2) | Frame Shift Ins (INS) | VAF 47/243 reads (19%) | called by mutect2, pindel, varscan2
- TRPC4 | c.451del p.H151Ifs*7 | Frame Shift Del (DEL) | VAF 45/156 reads (29%) | called by mutect2, pindel, varscan2
- ZMYM2 | c.3290_3291del p.E1097Vfs*5 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel
- ARHGAP29 | c.753T>C p.I251= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99557961; called by muse, mutect2, varscan2
- ATP10A | c.1803C>A p.S601= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100791101; called by muse, mutect2, varscan2
- B4GALNT3 | c.2490G>A p.E830= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV99842851; called by muse, mutect2, varscan2
- BTRC | c.828A>T p.I276= (on ENST00000370187 / NM_033637.4; = p.I240= on NM_003939.5) | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV100927788; called by muse, mutect2, varscan2
- C8B | c.330T>C p.C110= | Silent (SNP) | VAF 30/261 reads (11%) | catalogued as rs545739274, COSV100980750; called by muse, mutect2, varscan2
- CADM1 | c.498C>T p.C166= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV100522493; called by muse, mutect2, varscan2
- CASK | c.2491C>T p.L831= (on ENST00000378163 / NM_001367721.1; = p.L826= on NM_003688.3) | Silent (SNP) | VAF 29/42 reads (69%) | catalogued as COSV100587010; called by muse, mutect2, varscan2
- CCIN | c.1245C>T p.G415= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV100631801; called by muse, mutect2, varscan2
- CDCP1 | c.2263C>T p.L755= | Silent (SNP) | VAF 72/115 reads (63%) | catalogued as COSV56105697; called by muse, mutect2, varscan2
- CDSN | c.570C>A p.S190= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as COSV99456795; called by muse, mutect2, varscan2
- CSMD3 | c.7425T>A p.P2475= (on ENST00000297405 / NM_001363185.1; = p.P2371= on NM_052900.3) | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99831355; called by muse, mutect2, varscan2
- CTNNB1 | c.780C>T p.H260= | Silent (SNP) | VAF 57/97 reads (59%) | catalogued as rs776805998, COSV100846201; called by muse, mutect2, varscan2
- DNAI2 | c.471C>T p.D157= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100209714; called by muse, mutect2, varscan2
- DNMT3A | c.1479C>T p.I493= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as COSV99261636; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.138G>A p.E46= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV101236921, COSV66965366; called by muse, mutect2, varscan2
- EN1 | c.798G>A p.S266= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs368737948, COSV99727129; called by mutect2, varscan2
- EPS8L2 | c.408G>A p.L136= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100585479; called by muse, mutect2, varscan2
- FAM83H | c.3087C>T p.N1029= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs768891623, COSV62030684; called by mutect2, varscan2
- FCN1 | c.90G>A p.A30= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs756412026, COSV65661957; called by muse, mutect2, varscan2
- GABRA6 | c.1119G>A p.R373= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV99194297, COSV99194594; called by muse, mutect2, varscan2
- HEATR1 | c.6390G>A p.Q2130= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as rs761488184, COSV100120424; called by muse, mutect2, varscan2
- HOXB2 | c.843G>A p.G281= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV100344562; called by muse, mutect2
- JPH1 | c.672C>G p.R224= | Silent (SNP) | VAF 13/126 reads (10%) | catalogued as rs1217086722, COSV100646541; called by muse, mutect2
- KIAA1755 | c.804C>T p.S268= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV99641855; called by muse, mutect2, varscan2
- LGR6 | c.2163G>A p.A721= (on ENST00000367278 / NM_001017403.1; = p.A669= on NM_021636.3) | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs140182035; called by muse, mutect2, varscan2
- LIX1 | c.45C>T p.V15= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV99172893; called by muse, mutect2, varscan2
- LRRC14 | c.972G>A p.E324= | Silent (SNP) | VAF 18/184 reads (10%) | catalogued as rs761117107, COSV99467433; called by muse, mutect2, varscan2
- MYH6 | c.3576G>A p.A1192= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs762573185, COSV62447713; called by muse, mutect2, varscan2
- MYPN | c.1500G>A p.L500= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs779611735, COSV100589850; called by mutect2, varscan2
- NAA15 | c.2535G>A p.E845= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99649467; called by muse, mutect2, varscan2
- NADK | c.1056G>A p.S352= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs950252701, COSV58277457; called by muse, mutect2, varscan2
- NCAPG2 | c.2208G>A p.Q736= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV99316836; called by muse, mutect2, varscan2
- NEB | c.12930C>T p.A4310= | Silent (SNP) | VAF 53/108 reads (49%) | catalogued as rs771890971, COSV51150059; called by muse, mutect2, varscan2
- PAK5 | c.666C>T p.A222= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100781194, COSV100781252; called by muse, mutect2, varscan2
- PARP10 | c.75G>A p.E25= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs1554749319, COSV100477921; called by muse, mutect2, varscan2
- PBRM1 | c.2658T>C p.L886= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99968293; called by muse, mutect2, varscan2
- PCDHA5 | c.1293G>A p.S431= | Silent (SNP) | VAF 12/177 reads (7%) | catalogued as rs374495677, COSV65351452; called by muse, mutect2
- PGGT1B | c.183G>A p.L61= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs776672665, COSV99685891; called by muse, mutect2, varscan2
- PIWIL3 | c.1500C>T p.P500= | Silent (SNP) | VAF 40/147 reads (27%) | catalogued as COSV100177528; called by muse, mutect2, varscan2
- PLG | c.1839C>T p.S613= | Silent (SNP) | VAF 35/107 reads (33%) | catalogued as COSV57523727; called by muse, mutect2, varscan2
- PLXND1 | c.2085C>T p.A695= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV100139526; called by muse, mutect2, varscan2
- PON2 | c.600C>T p.H200= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV99749627; called by muse, mutect2, varscan2
- RASSF4 | c.564G>A p.V188= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100436863; called by muse, mutect2, varscan2
- SDK1 | c.4278C>A p.T1426= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV101269186; called by muse, mutect2, varscan2
- SERPINA3 | c.267G>A p.L89= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV101261670; called by muse, mutect2, varscan2
- SETX | c.2064C>T p.C688= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV99809417; called by muse, mutect2, varscan2
- SLC8A3 | c.1356G>T p.T452= | Silent (SNP) | VAF 48/157 reads (31%) | catalogued as rs777810742, COSV100776086; called by muse, mutect2, varscan2
- STARD13 | c.1689T>C p.P563= (on ENST00000336934 / NM_001243476.3; = p.P445= on NM_052851.3) | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV99715709; called by muse, mutect2, varscan2
- SURF4 | c.147C>T p.S49= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs782367838, COSV64339016; called by muse, mutect2, varscan2
- TECPR2 | c.1743G>T p.L581= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100849923; called by muse, mutect2, varscan2
- TINAG | c.1260A>T p.T420= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV99449272; called by muse, mutect2, varscan2
- TMEM168 | c.1605C>G p.S535= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV100454506, COSV100454592; called by muse, mutect2, varscan2
- USP8 | c.2670G>C p.R890= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100208936; called by muse, mutect2, varscan2
- VN1R2 | c.984C>T p.Y328= | Silent (SNP) | VAF 47/160 reads (29%) | catalogued as rs758880285, COSV59039229; called by muse, mutect2, varscan2
- ZNF486 | c.612T>C p.D204= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100631198; called by muse, mutect2, varscan2
- ZNF808 | c.2121C>T p.Y707= | Silent (SNP) | VAF 21/303 reads (7%) | catalogued as COSV100707878; called by muse, mutect2
- IL19 | c.-85A>T | 5'UTR (SNP) | VAF 38/124 reads (31%) | catalogued as rs767460276, COSV100534619; called by muse, mutect2, varscan2
